TARGET case TARGET-30-PAIVHE — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6d07ecd4-e96c-51ff-8a00-952e3c785871

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 3 years; Vital status: Dead; Days to death: 1,605 days (4.4 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Classification of tumor: primary; Age at diagnosis: 3.1 years (1,123 days); Year of diagnosis: 1999; Days to last follow up: 1,605 days (4.4 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Low.
   Pathology details: Necrosis percent: 10; Percent tumor nuclei: 90.
   Treatment given: Protocol identifier: 9047.
   Treatment given: Protocol identifier: P9462.
   Treatment given: Protocol identifier: ANBL0321.

Follow-up (2 entries)
- Days to follow up: 672 days (1.8 years); Days to first event: 672 days (1.8 years); First event: Event.
- Days to follow up: 1,605 days (4.4 years); Year of follow up: 2003.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PAIVHE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAIVHE-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- First Event: Event
- Overall Survival Time in Days: 1605
- Protocol: 9047, P9462, ANBL0321
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.06
- Histology: Unfavorable
- MKI: Low
- ICDO Description: Adrenal gland, NOS Suprarenal gland Adrenal, NOS
- Percent Tumor v/s Stroma: 70/30
